Somatic mutation profile of tumor specimen ALCH-B2QS-TTP1-A (aliquot ALCH-B2QS-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2QS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 46.8 years (17,089 days).
Specimen ALCH-B2QS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44980d1b-916a-4320-9989-d80633d19847.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QS-NB1-A (Blood Derived Normal), aliquot ALCH-B2QS-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1adcc502-bde0-4d0a-b348-af9282e5a717

The open-access MAF lists 321 somatic variants for this specimen: 217 protein-altering or splice-affecting, 63 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 63, Intron 16, Nonsense Mutation 14, RNA 11, Frame Shift Del 8, Splice Site 7, 5'UTR 7, Splice Region 6, 3'UTR 5, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 81/359 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 32/138 reads (23%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 123/772 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV51842410; called by muse, mutect2, varscan2
- APOH | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1335081795, COSV52773003; called by muse, mutect2, varscan2
- ARHGEF3 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 108/331 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs1380375876; called by muse, mutect2, varscan2
- BEGAIN | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1171501044; called by muse, mutect2
- BIN2 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.921); catalogued as COSV57207035; called by muse, mutect2, varscan2
- CBX6 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53321122; called by muse, mutect2, varscan2
- CEACAM7 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 76/203 reads (37%) | catalogued as COSV50072597; called by muse, mutect2, varscan2
- CFAP58 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV63833785; called by muse, mutect2, varscan2
- CFHR5 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201808624, COSV99888045; called by muse, mutect2, varscan2
- CNTN1 | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1212478742; called by muse, mutect2, varscan2
- COL22A1 | c.428A>T p.K143M | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV57323267; called by muse, mutect2, varscan2
- CSMD3 | c.5417T>G p.F1806C (on ENST00000297405 / NM_001363185.1; = p.F1702C on NM_052900.3) | Missense Mutation (SNP) | VAF 198/573 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1465046491; called by muse, mutect2, varscan2
- CSMD3 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52296419; called by muse, mutect2, varscan2
- CTAGE1 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV66943336; called by muse, mutect2, varscan2
- CUX1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs1212077259, COSV99471490; called by muse, mutect2, varscan2
- CYP3A5 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1392612248; called by muse, mutect2, varscan2
- DCHS1 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146693870; called by muse, mutect2, varscan2
- DIAPH3 | c.2319C>G p.F773L (on ENST00000400324 / NM_001042517.2; = p.F510L on NM_030932.3) | Missense Mutation (SNP) | VAF 94/358 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1443691828; called by muse, mutect2, varscan2
- DNAH5 | c.3262+1G>T p.X1088_splice | Splice Site (SNP) | VAF 88/432 reads (20%) | catalogued as rs757275351; called by muse, mutect2
- DPYD | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs573299212, COSV64615892; called by muse, mutect2, varscan2
- ERICH3 | c.2455C>A p.P819T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs140571107; called by muse, mutect2, varscan2
- EZH2 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100234659; called by muse, mutect2, varscan2
- FAM111A | c.1289G>T p.W430L | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs1289685324; called by muse, mutect2, varscan2
- GRM1 | c.2647G>T p.A883S | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs376290378; called by muse, mutect2, varscan2
- H3-2 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV67396890; called by muse, mutect2, varscan2
- IL27RA | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54600999; called by muse, mutect2, varscan2
- ITGB3 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV71385394; called by muse, mutect2, varscan2
- KIF21B | c.3629G>T p.R1210L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV59763688; called by muse, mutect2, varscan2
- KL | c.2957T>C p.I986T | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs943876768; called by muse, mutect2, varscan2
- KMT2D | c.14996G>T p.G4999V | Missense Mutation (SNP) | VAF 118/520 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1382788744; called by muse, mutect2, varscan2
- KRTAP21-2 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 280/574 reads (49%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs775888558; called by muse, varscan2
- LMAN1L | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV100547610; called by muse, mutect2, varscan2
- LRFN5 | c.1067C>A p.T356N | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV53257302; called by muse, mutect2, varscan2
- LRIG3 | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.156); catalogued as rs1461608223; called by muse, mutect2, varscan2
- LRP12 | c.1963A>G p.T655A | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs774082936; called by muse, mutect2, varscan2
- MAGEB6 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV66872202; called by muse, mutect2, varscan2
- MAGEC1 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV53574142; called by muse, mutect2, varscan2
- MUC15 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475211916; called by muse, mutect2, varscan2
- MYH2 | c.2420A>G p.Y807C | Missense Mutation (SNP) | VAF 145/557 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs1416226005; called by muse, mutect2, varscan2
- NAGK | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV54904342; called by muse, mutect2, varscan2
- ONECUT2 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as rs781167570; called by muse, varscan2
- OPLAH | c.3256G>T p.V1086L | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV70679018; called by muse, mutect2, varscan2
- OR4X1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs372724804, COSV60723330; called by muse, mutect2
- PALM3 | c.52C>T p.R18W (on ENST00000340790; = p.R33W on NM_001145028.2) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374025379, COSV54600951; called by muse, mutect2, varscan2
- PARP9 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772179302; called by muse, mutect2, varscan2
- PCDHA8 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV65336233, COSV65336978; called by muse, mutect2, varscan2
- PDE1C | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV99061752; called by muse, mutect2, varscan2
- PDZRN3 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55209343; called by muse, mutect2, varscan2
- PDZRN3 | c.1406G>C p.R469P | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55193713; called by muse, mutect2, varscan2
- RASGRP4 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773554915; called by muse, varscan2
- RELN | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 148/662 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100634497; called by muse, mutect2, varscan2
- RIF1 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV54620167; called by muse, mutect2, varscan2
- RTL6 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV57980212; called by muse, mutect2, varscan2
- RYR1 | c.2149G>T p.G717* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV62100591; called by muse, mutect2, varscan2
- RYR1 | c.11132C>T p.T3711M | Missense Mutation (SNP) | VAF 84/428 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs375915752; called by muse, varscan2
- SCUBE2 | c.2515G>A p.G839R (on ENST00000649792 / NM_001367977.2; = p.G782R on NM_020974.3) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs763759464; called by muse, mutect2
- SERPINI1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1344969234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC30A2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs905698847, COSV100958623; called by muse, mutect2, varscan2
- SLC3A1 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53224777; called by muse, mutect2
- SLC47A1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201666623, COSV99565503; called by muse, mutect2, varscan2
- STIM1 | c.1212T>A p.D404E | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.787); catalogued as COSV100331111; called by muse, mutect2, varscan2
- SYNE1 | c.5792C>A p.S1931Y (on ENST00000367255 / NM_182961.4; = p.S1938Y on NM_033071.3) | Missense Mutation (SNP) | VAF 128/678 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs766606624; called by muse, mutect2, varscan2
- TADA3 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs201486781; called by muse, mutect2, varscan2
- TAP1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV62755409; called by muse, mutect2, varscan2
- THSD7A | c.3797C>A p.A1266E | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69855432; called by muse, mutect2, varscan2
- TOR4A | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs147554658; called by muse, mutect2, varscan2
- TRIM64B | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs1377322444; called by muse, mutect2, varscan2
- TTC13 | c.2357A>G p.K786R | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.215); catalogued as rs1256164936; called by muse, mutect2, varscan2
- USH2A | c.10478G>T p.R3493I | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs201182885; called by muse, mutect2, varscan2
- USH2A | c.3315C>T p.Y1105= | Splice Region (SNP) | VAF 63/447 reads (14%) | catalogued as COSV56449264; called by muse, mutect2, varscan2
- VCAN | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425068; called by muse, mutect2, varscan2
- WNT5A | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767068436; called by muse, mutect2, varscan2
- Z83844.2 | c.498C>T p.L166= | Splice Region (SNP) | VAF 46/147 reads (31%) | catalogued as COSV60930025; called by muse, mutect2, varscan2
- ZC3HC1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 123/586 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs750648449, COSV100316131; called by muse, mutect2, varscan2
- ZDHHC13 | c.391A>G p.M131V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757029777; called by muse, mutect2, varscan2
- ZNF28 | c.1512C>A p.F504L | Missense Mutation (SNP) | VAF 189/395 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60425816; called by muse, mutect2, varscan2
- ZNF438 | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 110/338 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59194653; called by muse, mutect2, varscan2
- ZNF676 | c.1028G>T p.C343F (on ENST00000650058; = p.C311F on NM_001001411.3) | Missense Mutation (SNP) | VAF 91/658 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68092245; called by muse, mutect2, varscan2
- ZNF692 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 123/668 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV60659240; called by muse, mutect2, varscan2
- ZNF729 | c.3685C>A p.H1229N | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1480805880; called by muse, mutect2, varscan2
- AARS1 | c.797A>T p.Y266F | Missense Mutation (SNP) | VAF 118/371 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABHD12 | c.1029+6T>C | Splice Region (SNP) | VAF 92/558 reads (16%) | called by muse, mutect2, varscan2
- ABHD12 | c.317-2A>T p.X106_splice | Splice Site (SNP) | VAF 144/555 reads (26%) | called by muse, mutect2, varscan2
- ABI3BP | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- AC126283.2 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1A2 | c.450C>A p.Y150* | Nonsense Mutation (SNP) | VAF 47/231 reads (20%) | called by muse, mutect2, varscan2
- AMPD1 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 98/593 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD26 | c.4430A>G p.Q1477R | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ANO5 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APLF | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2
- ARHGAP33 | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ARMC3 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- ATP10A | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 28/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP11B | c.3408G>A p.M1136I | Missense Mutation (SNP) | VAF 34/1245 reads (3%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- ATP13A5 | c.3574T>A p.Y1192N | Missense Mutation (SNP) | VAF 30/794 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- BSG | c.341dup p.D115Gfs*47 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- BTBD17 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C14orf39 | c.1058+1G>T p.X353_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- C14orf39 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C2CD2 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CACNA1E | c.2702dup p.G902Rfs*8 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- CBLC | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCL1 | c.273C>A p.C91* | Nonsense Mutation (SNP) | VAF 111/437 reads (25%) | called by muse, mutect2, varscan2
- CECR2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL22A1 | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A2 | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CSAD | c.812A>T p.H271L (on ENST00000444623 / NM_001244705.2; = p.H298L on NM_015989.5) | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSDE1 | c.2288A>G p.D763G (on ENST00000358528 / NM_001007553.3; = p.D732G on NM_007158.6) | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTR9 | c.1793A>T p.Q598L | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUX2 | c.1106T>G p.L369R | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2C9 | c.1146del p.K383Rfs*6 | Frame Shift Del (DEL) | VAF 106/385 reads (28%) | called by mutect2, pindel, varscan2
- DGCR8 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLC1 | c.4413A>T p.E1471D (on ENST00000276297 / NM_001348081.2; = p.E1034D on NM_006094.5) | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DNAAF5 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DTHD1 | c.106G>A p.V36I (on ENST00000456874; = p.V161I on NM_001170700.3) | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EBI3 | c.380-1G>T p.X127_splice | Splice Site (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- EDC4 | c.3912G>T p.Q1304H | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EPOP | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FAM167B | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FAM172A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/187 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- FNDC1 | c.4731G>T p.E1577D | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GALNT2 | c.1561A>T p.K521* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- GCC1 | c.1789A>C p.T597P | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GFI1 | c.1192T>C p.C398R | Missense Mutation (SNP) | VAF 28/715 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GPR142 | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GREB1L | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 78/313 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- GRID2IP | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 130/468 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GRIK1 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- GRIN1 | c.1946C>A p.A649D | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN3A | c.49T>A p.L17M | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); called by muse, mutect2
- HAS1 | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HDAC9 | c.2799del p.F933Lfs*4 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel
- HMCN1 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 90/453 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HPS5 | c.1499A>T p.H500L (on ENST00000349215 / NM_181507.2; = p.H386L on NM_007216.4) | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1D-43 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 230/876 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- INO80 | c.1604A>C p.Q535P | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IRAK2 | c.766del p.A256Qfs*114 | Frame Shift Del (DEL) | VAF 43/158 reads (27%) | called by mutect2, pindel, varscan2
- IRF6 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- ITPR3 | c.3403A>T p.K1135* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | called by muse, mutect2, varscan2
- KCNA5 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 119/463 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLRB1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 81/190 reads (43%) | called by muse, mutect2, varscan2
- KLRF2 | c.578G>C p.C193S | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.9212-1G>T p.X3071_splice | Splice Site (SNP) | VAF 150/590 reads (25%) | called by muse, mutect2, varscan2
- LINS1 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LOXHD1 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LRGUK | c.1983+1G>T p.X661_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- MAGEB6B | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MEPCE | c.1470C>G p.Y490* | Nonsense Mutation (SNP) | VAF 76/363 reads (21%) | called by muse, mutect2, varscan2
- MKI67 | c.7251A>T p.L2417F | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NACAD | c.3008C>A p.P1003Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NETO1 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPHS1 | c.2650C>A p.L884I | Missense Mutation (SNP) | VAF 116/450 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NUS1 | c.660T>A p.D220E | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OBSCN | c.12026T>G p.V4009G | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OCLN | c.1568A>T p.*523Lext*13 | Nonstop Mutation (SNP) | VAF 71/302 reads (24%) | called by muse, mutect2, varscan2
- OR2J3 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- OR2T10 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR52B4 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR6N2 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8H1 | c.788A>T p.K263M | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- P3H3 | c.1748_1753del p.V583_H584del | In Frame Del (DEL) | VAF 107/248 reads (43%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.428T>A p.F143Y | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHGB5 | c.1912C>A p.L638M | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PKDREJ | c.3139G>T p.A1047S | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKHD1L1 | c.6731G>T p.G2244V | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEC | c.9827C>T p.S3276F (on ENST00000322810 / NM_201380.4; = p.S3166F on NM_000445.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by mutect2, varscan2
- POLR2E | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- PRMT6 | c.228del p.N77Tfs*20 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- PTGES3 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RABGEF1 | c.936C>A p.F312L (on ENST00000439720 / NM_001287061.2; = p.F299L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- RASA3 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RASGRF2 | c.1661T>C p.I554T | Missense Mutation (SNP) | VAF 113/432 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RGPD1 | c.4292G>T p.R1431L (on ENST00000409776; = p.R1439L on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by mutect2, varscan2
- RNF20 | c.2710A>C p.K904Q | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- RYR2 | c.13966A>G p.K4656E | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SCGN | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SHKBP1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIGLEC15 | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC13A3 | c.1100G>T p.W367L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SLC16A1 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A4 | c.918G>C p.W306C | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC25A28 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC30A10 | c.511del p.Q171Rfs*21 | Frame Shift Del (DEL) | VAF 32/229 reads (14%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 114/654 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLCO1B1 | c.1466G>A p.C489Y | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN14 | c.1649T>A p.V550E | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLIT1 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SORCS3 | c.2036C>A p.S679Y | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPAM1 | c.954A>G p.Q318= | Splice Region (SNP) | VAF 6/27 reads (22%) | called by muse, varscan2
- SPATA4 | c.797del p.P266Lfs*6 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | called by mutect2, pindel, varscan2
- SPRED1 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SUGT1 | c.521A>G p.Y174C (on ENST00000343788 / NM_001130912.3; = p.Y142C on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TAF15 | c.913G>T p.G305* (on ENST00000605844 / NM_139215.3; = p.G302* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 66/330 reads (20%) | called by muse, mutect2, varscan2
- TAS2R46 | c.692_693del p.V231Dfs*22 | Frame Shift Del (DEL) | VAF 74/256 reads (29%) | called by pindel, varscan2
- TBC1D2B | c.1282A>C p.T428P | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TEX13C | c.2192G>T p.R731I | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- TEX15 | c.4385G>A p.W1462* (on ENST00000256246; = p.W1845* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- TIAM1 | c.1335_1336del p.L446Gfs*61 | Frame Shift Del (DEL) | VAF 42/110 reads (38%) | called by mutect2, pindel, varscan2
- TMC7 | c.1024A>T p.R342* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | called by muse, varscan2
- TMEM102 | c.1424G>C p.R475P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TMEM141 | c.204G>T p.V68= | Splice Region (SNP) | VAF 87/185 reads (47%) | called by muse, mutect2, varscan2
- TTC28 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, varscan2
- TTLL4 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.22883C>A p.S7628Y (on ENST00000591111; = p.S6701Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TTN | c.5167G>C p.E1723Q (on ENST00000591111; = p.E1677Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/119 reads (5%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.2861T>G p.V954G (on ENST00000591111; = p.V908G on NM_003319.4) | Missense Mutation (SNP) | VAF 57/255 reads (22%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UHRF1BP1 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.7219C>T p.Q2407* | Nonsense Mutation (SNP) | VAF 75/301 reads (25%) | called by muse, mutect2, varscan2
- WDFY4 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- WDFY4 | c.3759C>A p.N1253K | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.188); called by muse, mutect2
- XIRP2 | c.652-1G>T p.X218_splice (on ENST00000628543; = p.X393_splice on NM_152381.6) | Splice Site (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- ZNF211 | c.1100G>T p.R367M (on ENST00000347302 / NM_198855.4; = p.R380M on NM_006385.5) | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZNF311 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by mutect2, varscan2
- ZNF727 | c.455A>T p.K152I | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF98 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- APOBEC3B | c.561G>A p.E187= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- BIRC7 | c.543A>G p.E181= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs1393893341; called by muse, mutect2
- BMPER | c.759C>T p.Y253= | Silent (SNP) | VAF 115/487 reads (24%) | catalogued as rs377437543; called by muse, mutect2, varscan2
- BORA | c.159G>T p.R53= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs1378330008; called by muse, mutect2, varscan2
- CCNQ | c.648G>T p.P216= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV52344024; called by muse, mutect2, varscan2
- CDK17 | c.1389A>T p.S463= | Silent (SNP) | VAF 67/279 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.7785A>G p.L2595= (on ENST00000520002; = p.L2594= on NM_033225.6) | Silent (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- CUL9 | c.4851G>T p.V1617= | Silent (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- CYP4B1 | c.831C>T p.I277= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs934297858; called by muse, mutect2, varscan2
- DHX38 | c.2937G>C p.S979= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV51697231; called by muse, mutect2, varscan2
- EIF4G1 | c.4138C>T p.L1380= (on ENST00000346169 / NM_198241.3; = p.L1185= on NM_004953.5) | Silent (SNP) | VAF 100/604 reads (17%) | called by muse, mutect2, varscan2
- ELOA | c.39C>G p.R13= | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as rs778839375; called by muse, mutect2, varscan2
- EPOP | c.1119G>T p.G373= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- EPOR | c.483C>T p.H161= | Silent (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- EVPL | c.5529G>A p.T1843= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs771478916, COSV56910360; called by muse, mutect2, varscan2
- FAT1 | c.1596G>T p.R532= | Silent (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- GREM2 | c.477C>A p.S159= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV58947524, COSV58955345; called by muse, mutect2
- GUCY2D | c.1719C>T p.I573= | Silent (SNP) | VAF 125/458 reads (27%) | catalogued as COSV54698872; called by muse, mutect2, varscan2
- HEPH | c.2982C>A p.G994= (on ENST00000343002; = p.G727= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- HMCN1 | c.11190T>A p.T3730= | Silent (SNP) | VAF 97/488 reads (20%) | called by muse, mutect2, varscan2
- IMPG1 | c.1113G>T p.V371= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as COSV64059821; called by muse, mutect2, varscan2
- INHBA | c.1263G>A p.E421= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1350905493; called by muse, mutect2
- KLHL29 | c.204A>T p.T68= | Silent (SNP) | VAF 101/323 reads (31%) | called by muse, mutect2, varscan2
- LRFN5 | c.1896C>A p.S632= | Silent (SNP) | VAF 103/395 reads (26%) | called by muse, mutect2, varscan2
- MON1B | c.1584C>T p.S528= | Silent (SNP) | VAF 64/281 reads (23%) | catalogued as rs755766952; called by muse, mutect2, varscan2
- MYH13 | c.3880C>A p.R1294= | Silent (SNP) | VAF 68/242 reads (28%) | catalogued as COSV52822044; called by muse, mutect2, varscan2
- MYLK | c.2163C>A p.P721= | Silent (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
- NCOR1 | c.4368C>A p.P1456= | Silent (SNP) | VAF 113/383 reads (30%) | catalogued as COSV51969228, COSV99251502; called by muse, mutect2, varscan2
- NES | c.1890G>A p.K630= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV63960791; called by muse, mutect2, varscan2
- NLRP14 | c.2856T>A p.V952= | Silent (SNP) | VAF 63/290 reads (22%) | called by muse, mutect2
- NLRP3 | c.2565G>A p.L855= | Silent (SNP) | VAF 78/442 reads (18%) | called by muse, mutect2, varscan2
- NRXN1 | c.1263C>T p.S421= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV58475566; called by muse, mutect2, varscan2
- OLA1 | c.855G>A p.A285= | Silent (SNP) | VAF 31/298 reads (10%) | catalogued as rs757606285, COSV52973775; called by muse, mutect2, varscan2
- OR10A5 | c.543C>T p.D181= | Silent (SNP) | VAF 125/415 reads (30%) | called by muse, mutect2, varscan2
- OR10K1 | c.189T>A p.L63= | Silent (SNP) | VAF 126/401 reads (31%) | called by muse, mutect2, varscan2
- OR1B1 | c.528C>A p.G176= | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- OR5AP2 | c.96C>A p.V32= | Silent (SNP) | VAF 51/228 reads (22%) | called by muse, mutect2, varscan2
- OR6N2 | c.375C>T p.A125= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs759458549, COSV59412769; called by muse, mutect2, varscan2
- PDE1C | c.1491T>A p.S497= | Silent (SNP) | VAF 48/213 reads (23%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7047A>T p.A2349= | Silent (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.918G>A p.K306= | Silent (SNP) | VAF 131/425 reads (31%) | catalogued as rs1198286531; called by muse, mutect2, varscan2
- POTEE | c.2235G>C p.G745= | Silent (SNP) | VAF 48/370 reads (13%) | called by muse, mutect2, varscan2
- PPP4R3C | c.2478G>A p.K826= | Silent (SNP) | VAF 16/24 reads (67%) | called by muse, varscan2
- PRLR | c.951A>C p.V317= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- RELN | c.4473G>A p.R1491= | Silent (SNP) | VAF 151/667 reads (23%) | called by muse, mutect2, varscan2
- RHPN1 | c.789G>C p.A263= | Silent (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- ROCK2 | c.3726A>G p.Q1242= | Silent (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2
- RSRP1 | c.237G>C p.R79= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs780822299; called by muse, mutect2, varscan2
- RYR2 | c.7347G>A p.G2449= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV63713648; called by muse, mutect2
- SI | c.4704C>G p.P1568= | Silent (SNP) | VAF 49/274 reads (18%) | called by muse, mutect2, varscan2
- SLC49A4 | c.261C>T p.S87= | Silent (SNP) | VAF 118/379 reads (31%) | catalogued as rs1348834639; called by muse, mutect2, varscan2
- SLFN12 | c.1294C>T p.L432= | Silent (SNP) | VAF 66/336 reads (20%) | catalogued as COSV59226477; called by muse, mutect2, varscan2
- SNPH | c.936T>C p.R312= | Silent (SNP) | VAF 40/156 reads (26%) | called by mutect2, varscan2
- SPATA31D1 | c.444C>A p.S148= | Silent (SNP) | VAF 107/528 reads (20%) | called by muse, mutect2, varscan2
- STXBP5 | c.867A>C p.P289= | Silent (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- SYNM | c.4260T>C p.R1420= | Silent (SNP) | VAF 99/634 reads (16%) | called by muse, mutect2, varscan2
- TAS2R9 | c.621A>G p.R207= | Silent (SNP) | VAF 161/332 reads (48%) | called by muse, mutect2, varscan2
- TEX13C | c.1989G>A p.L663= | Silent (SNP) | VAF 153/332 reads (46%) | called by muse, varscan2
- USH2A | c.2733C>A p.T911= | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as COSV56348189; called by muse, mutect2, varscan2
- ZNF33A | c.204A>G p.E68= | Silent (SNP) | VAF 64/250 reads (26%) | catalogued as rs773345010; called by muse, mutect2, varscan2
- ZNF479 | c.1392C>A p.P464= | Silent (SNP) | VAF 97/499 reads (19%) | catalogued as COSV100482906; called by muse, mutect2, varscan2
- ZNF804B | c.438C>A p.L146= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV60821880; called by muse, mutect2, varscan2
- ZNF831 | c.2353C>T p.L785= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1240210192; called by muse, mutect2, varscan2
- BIRC8 | n.1723G>T | RNA (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- BRD7 | c.-9C>G | 5'UTR (SNP) | VAF 16/79 reads (20%) | catalogued as rs775996573; called by muse, mutect2, varscan2
- C19orf12 | c.*173G>A | 3'UTR (SNP) | VAF 226/726 reads (31%) | called by muse, mutect2, varscan2
- CCDC93 | c.1351-686G>C | Intron (SNP) | VAF 56/295 reads (19%) | called by muse, mutect2, varscan2
- CDK9 | c.-71C>T | 5'UTR (SNP) | VAF 21/37 reads (57%) | catalogued as rs1260140500; called by muse, mutect2, varscan2
- COX7A2 | c.204+20G>T | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- DCAF17 | c.*3645C>T | 3'UTR (SNP) | VAF 139/447 reads (31%) | called by muse, mutect2, varscan2
- DDX39B | c.-2-596A>T | Intron (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- DENND1B | c.83-20557del | Intron (DEL) | VAF 81/492 reads (16%) | called by mutect2, pindel, varscan2
- DPPA4 | c.679+86C>A | Intron (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- DST | c.4297-1314G>A | Intron (SNP) | VAF 44/463 reads (10%) | called by muse, mutect2
- EPB41 | c.1845+40G>A | Intron (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- ESR1 | c.-43C>G | 5'UTR (SNP) | VAF 40/215 reads (19%) | called by muse, mutect2, varscan2
- GCAT | c.430-150G>T | Intron (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2
- GOLGA6L3 | n.459A>T | RNA (SNP) | VAF 54/966 reads (6%) | called by muse, mutect2
- GPRC5C | c.1187-305G>A | Intron (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2
- HERC2P3 | chr15:20457457 G>T | 5'Flank (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- HSF1 | c.-14C>G | 5'UTR (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- HTR3A | c.*80C>G | 3'UTR (SNP) | VAF 65/167 reads (39%) | called by muse, mutect2, varscan2
- IMPACT | c.-48C>T | 5'UTR (SNP) | VAF 9/22 reads (41%) | catalogued as rs1157028637; called by muse, mutect2, varscan2
- KCNMB2 | c.-21C>G | 5'UTR (SNP) | VAF 52/203 reads (26%) | catalogued as rs756918910, COSV100843911; called by muse, mutect2, varscan2
- KIR3DX1 | n.1157C>A | RNA (SNP) | VAF 95/441 reads (22%) | catalogued as rs1348145238, COSV55597640; called by muse, mutect2, varscan2
- LINC01100 | n.388C>A | RNA (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- LINC01630 | n.219+73169G>A | Intron (SNP) | VAF 65/206 reads (32%) | catalogued as rs1014903998; called by muse, mutect2, varscan2
- LINC02740 | n.40G>T | RNA (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1553-67G>A | Intron (SNP) | VAF 20/244 reads (8%) | catalogued as rs760858306; called by muse, mutect2
- MYADML | n.681C>A | RNA (SNP) | VAF 57/201 reads (28%) | called by muse, mutect2, varscan2
- NBPF22P | n.1213C>G | RNA (SNP) | VAF 123/724 reads (17%) | called by muse, mutect2, varscan2
- NOL4L-DT | n.633C>A | RNA (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- NTPCR | c.505-1740C>A | Intron (SNP) | VAF 47/386 reads (12%) | catalogued as COSV100786664; called by muse, mutect2, varscan2
- OR2W5 | n.842T>A | RNA (SNP) | VAF 72/436 reads (17%) | catalogued as rs1334596969; called by muse, mutect2, varscan2
- PDE7B | c.711+174G>T | Intron (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159741 C>A | 5'Flank (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- RNF8 | c.*48T>A | 3'UTR (SNP) | VAF 59/328 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-2 | n.29T>C | RNA (SNP) | VAF 99/476 reads (21%) | catalogued as rs756396224; called by muse, mutect2, varscan2
- SNX5 | c.51+5499G>T | Intron (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2290G>T | RNA (SNP) | VAF 151/600 reads (25%) | called by muse, mutect2, varscan2
- SYBU | c.-110A>T | 5'UTR (SNP) | VAF 109/239 reads (46%) | called by muse, mutect2, varscan2
- TEX51 | c.365-37C>G | Intron (SNP) | VAF 52/208 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.34265-4477C>T | Intron (SNP) | VAF 67/315 reads (21%) | catalogued as rs769994195; called by muse, mutect2, varscan2
- ZNF217 | c.*75C>T | 3'UTR (SNP) | VAF 51/223 reads (23%) | called by muse, mutect2, varscan2
